Surgical pathology report (de-identified scan), TCGA case TCGA-DU-5852, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-5852-01A (Primary Tumor).

[page 1 of 5]
[REDACTED]

Surgical Pathology Report

TCGA--DU-5852

[REDACTED]

Taken: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

=====

CLINICAL HISTORY

The patient [REDACTED] with [REDACTED].
Currently
the patient has a lucent, circumscribed lesion in the parahippocampal
gyrus
and hippocampus, which on FLAIR involves nearly the entire temporal
lobe.

OPERATIVE DIAGNOSES

Epilepsy

Operation/Specimen: A: Brain, medial temporal tumor, biopsy
B: Brain, posterior tumor, biopsy

PATHOLOGICAL DIAGNOSIS:

A. Brain, medial temporal tumor, biopsy: Anaplastic oligoastrocytoma
(WHO
Grade III) (see comment).

B. Brain, posterior tumor, biopsy: Anaplastic oligoastrocytoma (WHO
Grade
III) (see comment).

COMMENT

Permanent sections are in keeping with agreement of the frozen section
diagnoses. Sections of A. and B. show a proliferation of moderately
pleomorphic round to oval and occasionally angular cells. Infiltrate
cortex

shows perineuronal tumor cell satellitosis. Scattered mitotic figures
are

identified. Vascular proliferation and necrosis are not seen.

Immunohistochemical stains performed on part B. show positive GFAP
staining of

reactive astrocytes and occasional tumor cells, some of which show a
thin rim

of perinuclear staining. Corresponding [REDACTED] slides for
this

case are also reviewed.

[page 2 of 5]
Overall the tumor is most consistent with an anaplastic oligoastrocytoma, with the oligodendroglial component being dominant.

The Ki-67 labeling index is up to approximately 12%. Positive and negative controls show appropriate immunoreactivity.

Molecular studies show that the tumor is negative for 1p,19q LOH and positive for MGMT promoter methylation (see procedure addenda below).

=====

=
PROCEDURES/ADDENDA

Loss of Heterozygosity 1p, 19q Assay [REDACTED]

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are: D1S1592, D1S552, D1S468, D1S1612, D1S496, PLA2G4C, D19S606 and D19S1182

Results-Comments

Testing performed on DNA extracted from tumor paraffin block. DNA extracted from a corresponding blood specimen was used as normal reference control.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise

[page 3 of 5]
ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] as required by [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

Electronically Signed Out
[REDACTED]

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences. The analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the detection of methylated MGMT promoter sequences.

[page 4 of 5]
FDA COMMENT: "The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by [REDACTED] [REDACTED]. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED] logy
=====

INTRA-OPERATIVE CONSULTATION

A.

Brain, medial temporal tumor, biopsy: Cerebral cortex, and white matter, not diagnostic. There is not lymphoma. Firm blood clot, grossly. More tissue

will be submitted. [REDACTED] Touch preparation smears performed at [REDACTED]

[REDACTED] and results reported to the Physician of Record. [REDACTED]

B.

Posterior tumor, biopsy:

1. Hypercellular tissue, small cells (R/O glioma, other...) [REDACTED]

Touch

preparation smears performed at [REDACTED] and results reported to the Physician of Record.

2. Hypercellular tissue, slight atypia (R/O infiltrative process, glioma?

other) More tissue will be available [REDACTED]. Frozen section performed

[REDACTED] and results reported to the Physician of Record.

GROSS DESCRIPTION

A.

"Medial temporal tumor," received fresh, three fragments, 0.8 cm in aggregate.

Semi firm, tannish-white. In total, A1.

B.

"Posterior tumor," received fresh, multiple fragments, 1.4 x 1.5 x 0.9 cm in

aggregate. Semi firm, tannish-grey, focally hemorrhagic. Fragment of leptomeninges with engorged vessels. In total, B1-B3, frozen tissue

B4.

[page 5 of 5]
ICD-9(s):

345.11 345.11

Billing Fee Code(s):

Histo Data

Part A: Brain, medial temporal tumor, biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
TPS H/E x 1	1		

Part B: Brain, posterior tumor, biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
FS H/E x 1	1		
mGFAP-DA x 1	1		
H/E x 1	1		
LOH-curls x 1	1		
MGMT-curls x 1	1		
MIB1-DA x 1	1		
TPS Triage x 1	1		
H/E x 1	2		
H/E x 1	3		
mGFAP-DA x 1	4		
H/E x 1	4		
MIB1-DA x 1	4		

*** End of Report ***

Source: NCI Genomic Data Commons file 1e2d757b-7e13-4146-a8e1-18b854781322 (TCGA-DU-5852.A6C1F30A-8350-4FBC-9AF2-5333CBE273E6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).